Gene-level copy-number profile of tumor specimen TCGA-55-A491-01A from TCGA case TCGA-55-A491, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 81.0 years (29,593 days).
Specimen TCGA-55-A491-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.12d2f969-2231-4bbc-81c1-34b3ae8f80eb.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-55-A491-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b4c1912a-a83e-4106-9592-0f9103b93c93

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 3; copy number 2: 2,251; copy number 3: 16,390; copy number 4: 8,620; copy number 5: 5,504; copy number 6: 10,980; copy number 7: 5,356; copy number 8: 9,067; copy number 9: 553; copy number 10: 177; copy number 12: 354; copy number 13: 22; copy number 14: 31; copy number 17: 20; copy number 20: 411; copy number 25: 17; copy number 26: 40; copy number 40: 15.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-55-A491-01A-11D-A24C-01): tumor purity 0.45, ploidy 2.57, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 16,063 genes in 34 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:107,571,161–114,355,178, 204 genes, copy number 7 (broad region; genes not listed).
- chr1:169,310,665–204,829,274, 624 genes, copy number 8 (broad region; genes not listed).
- chr2:38,814–178,108,339, 3,050 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr3:93,843,764–198,222,513, 1,800 genes, copy number 8 (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 8–13 (broad region; genes not listed).
- chr5:149,730,298–149,855,022, 1 gene, copy number 8 (within-gene range 3–8): PPARGC1B.
- chr5:149,857,953–153,813,869, 73 genes, copy number 8 (within-gene range 3–8) (broad region; genes not listed).
- chr5:154,190,730–155,845,528, 30 genes, copy number 7: GALNT10, SAP30L-AS1, HNRNPA3P7, AC008625.1, MIR1294, RN7SL655P, SAP30L, HAND1, AC026688.2, AC026688.1, CIR1P1, MIR3141, MIR1303, Y_RNA, LARP1, RN7SL803P, AC008379.1, FAXDC2, Metazoa_SRP, MIR378H, CNOT8, GEMIN5, MRPL22, AC008410.1, KIF4B, AC010476.2, AC010476.1, AC010591.1, AC008725.1, RNA5SP199.
- chr5:156,019,228–156,039,977, 1 gene, copy number 7: AC011351.1.
- chr5:157,931,258–173,484,584, 205 genes, copy number 8–10 (broad region; genes not listed).
- chr5:173,642,519–176,659,054, 72 genes, copy number 7–12 (broad region; genes not listed).
- chr5:179,732,822–181,342,213, 78 genes, copy number 8 (within-gene range 5–8) (broad region; genes not listed).
- chr6:73,523,618–79,703,655, 71 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr6:82,892,390–90,587,072, 133 genes, copy number 7 (broad region; genes not listed).
- chr6:124,644,434–133,107,410, 123 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr7:21,381,363–57,485,895, 720 genes, copy number 8–9 (broad region; genes not listed).
- chr8:43,672,823–145,066,685, 1,536 genes, copy number 8 (broad region; genes not listed).
- chr9:14,475–7,961,224, 139 genes, copy number 7 (broad region; genes not listed).
- chr10:44,712–50,965,220, 917 genes, copy number 8 (broad region; genes not listed).
- chr10:51,062,579–51,320,660, 5 genes, copy number 8: AL731537.1, AC022537.1, MIR605, AC069079.1, RSU1P3.
- chr11:9,778,667–10,294,219, 1 gene, copy number 10 (within-gene range 5–10): SBF2.
- chr11:10,149,192–19,308,358, 194 genes, copy number 8–26 (broad region; genes not listed).
- chr11:19,380,484–19,401,981, 2 genes, copy number 8: NAV2-IT1, RNA5SP335.
- chr11:26,188,842–39,261,213, 181 genes, copy number 7–8 (within-gene range 6–8) (broad region; genes not listed).
- chr12:58,244,378–133,214,832, 1,484 genes, copy number 7–8 (broad region; genes not listed).
- chr17:22,331,597–27,991,787, 61 genes, copy number 7–40 (within-gene range 4–40) (broad region; genes not listed).
- chr17:33,791,838–35,009,743, 30 genes, copy number 8 (within-gene range 4–8): AC024614.4, AC024610.2, AC004147.4, AC024610.1, AC123769.1, TLK2P1, AC004147.1, AC004147.5, RNA5SP438, AC004147.3, AC004147.2, LINC01989, AC005549.1, CCL2, CCL7, CCL11, CCL8, AC011193.2, CCL13, CCL1, AC011193.1, C17orf102, TMEM132E, AC005691.1, AC005552.1, AC022903.1, CCT6B, AC022903.2, ZNF830, LIG3.
- chr17:35,018,660–35,018,991, 1 gene, copy number 8: AC004223.4.
- chr17:37,084,992–80,415,168, 1,497 genes, copy number 8 (broad region; genes not listed).
- chr19:22,518,414–40,751,553, 570 genes, copy number 9–20 (within-gene range 3–20) (broad region; genes not listed).
- chr20:6,446,723–45,317,824, 769 genes, copy number 7–9 (broad region; genes not listed).
- chr20:51,782,331–64,313,132, 306 genes, copy number 7 (broad region; genes not listed).
- chr21:26,953,961–27,492,261, 7 genes, copy number 7: MIR4759, GPX1P2, AP001605.1, AP001604.1, EIF4A1P1, RPL10P1, NCSTNP1.
- chr22:15,290,718–23,145,021, 468 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
